Somatic mutation profile of tumor specimen HTMCP-03-06-02146-01A (aliquot HTMCP-03-06-02146-01A-01D-5099) from CGCI case HTMCP-03-06-02146, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 35.7 years (13,034 days).
Specimen HTMCP-03-06-02146-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f967ca3-1316-49eb-b25c-ea1233daf6bc.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02146-10A (Blood Derived Normal), aliquot HTMCP-03-06-02146-10A-01D-5099; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7492fd5-694d-4700-b822-309cb24515ee

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 9, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1, Translation Start Site 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 13/112 reads (12%) | catalogued as rs1131690915, CM0910363, COSV57299384, COSV99927549; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFAP47 | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1488278882; called by muse, mutect2, varscan2
- COL8A1 | c.127C>G p.Q43E | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV99657037; called by muse, mutect2, varscan2
- CRACDL | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as rs1457317618, COSV67410271; called by muse, mutect2, varscan2
- FAT1 | c.11351-1G>C p.X3784_splice | Splice Site (SNP) | VAF 9/56 reads (16%) | catalogued as COSV101499657; called by muse, mutect2, varscan2
- FREM1 | c.4882C>G p.P1628A | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780384100; called by muse, mutect2, varscan2
- NFATC2 | c.1936C>T p.R646W | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773542213, COSV65358618; called by muse, mutect2, varscan2
- TLN1 | c.4664G>A p.R1555H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1219317167, COSV100147668, COSV100148271; called by muse, mutect2, varscan2
- ARID2 | c.4548G>C p.K1516N | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC88A | c.1537G>T p.E513* | Nonsense Mutation (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- FSIP2 | c.9290T>G p.L3097R | Missense Mutation (SNP) | VAF 56/325 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- HLA-F | c.340C>G p.H114D | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- HSD17B4 | c.415G>A p.E139K (on ENST00000414835 / NM_001199291.3; = p.E114K on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IPO4 | c.236+8G>C | Splice Region (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- LATS1 | c.1071_1074del p.M357Ifs*11 | Frame Shift Del (DEL) | VAF 72/212 reads (34%) | called by mutect2, pindel, varscan2
- LATS2 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NSD1 | c.1197G>C p.R399S | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PHF20L1 | c.318G>C p.K106N | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- PLXNA4 | c.4977G>T p.E1659D | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2
- USP32 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- VEPH1 | c.1746A>C p.R582S | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- CILP | c.1011G>A p.R337= | Silent (SNP) | VAF 21/91 reads (23%) | called by muse, mutect2, varscan2
- CREBBP | c.3864G>A p.R1288= | Silent (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- MUC5B | c.15771G>A p.K5257= | Silent (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- NRK | c.3750C>T p.F1250= | Silent (SNP) | VAF 38/191 reads (20%) | called by muse, mutect2, varscan2
- PARP4 | c.204C>T p.H68= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs772211405; called by muse, mutect2, varscan2
- PTPRT | c.2412C>T p.A804= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as rs368232579; called by muse, mutect2, varscan2
- SLITRK5 | c.1047C>T p.P349= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs753211474, COSV100281167; called by muse, mutect2, varscan2
- VWA3B | c.2700C>T p.N900= | Silent (SNP) | VAF 20/144 reads (14%) | catalogued as rs780619003; called by muse, mutect2, varscan2
- WDPCP | c.2169G>A p.L723= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs746225322; called by mutect2, varscan2
- NTRK3 | c.1586-40533C>T | Intron (SNP) | VAF 40/164 reads (24%) | catalogued as COSV100448009; called by muse, mutect2, varscan2
